Gene-level copy-number profile of tumor specimen TCGA-P3-A5QF-01A from TCGA case TCGA-P3-A5QF, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper Gum; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 49.4 years (18,035 days).
Specimen TCGA-P3-A5QF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.1fa3ce71-304e-4303-815c-c87af4a6f946.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-P3-A5QF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00898eec-23cd-48d0-87fd-15a90d1980c3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,310; copy number 2: 48,718; copy number 3: 2,498; copy number 4: 1,170; copy number 5: 7; copy number 6: 4; copy number 7: 109; copy number 9: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-P3-A5QF-01A-11D-A28Q-01): tumor purity 0.81, ploidy 1.97, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 123 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:80,442,081–81,297,345, 7 genes, copy number 5: AC108740.1, AC108690.1, AC068756.1, LINC02050, LINC02027, AC099542.2, AC099542.1.
- chr11:24,455,911–25,141,023, 4 genes, copy number 6: Y_RNA, LUZP2, AC115990.1, AC087373.1.
- chr11:31,509,755–37,702,220, 109 genes, copy number 7 (within-gene range 1–7) (broad region; genes not listed).
- chr14:91,060,333–91,225,632, 3 genes, copy number 9 (within-gene range 2–9): DGLUCY, RNU7-30P, SNORA11B.

Autosomal genes at a single copy (total copy number 1): 4,923. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
